Gene-level copy-number profile of tumor specimen TCGA-63-A5MP-01A from TCGA case TCGA-63-A5MP, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-63-A5MP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.9757ad68-2dfa-4656-86f1-2d1a0defad7b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-A5MP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2c175bdd-301a-4131-80bb-e0cdae5bb1df

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 4,299; copy number 2: 19,855; copy number 3: 18,920; copy number 4: 8,069; copy number 5: 5,621; copy number 6: 825; copy number 7: 951; copy number 8: 55; copy number 9: 409; copy number 10: 127; copy number 11: 111; copy number 12: 62; copy number 14: 156; copy number 16: 145; copy number 17: 80; copy number 18: 32; copy number 20: 76; copy number 22: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-A5MP-01A-11D-A26L-01): tumor purity 0.33, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,558 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:22,861,552–35,471,841, 258 genes, copy number 5–7 (broad region; genes not listed).
- chr2:37,562,486–54,972,025, 267 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr2:55,014,418–55,014,521, 1 gene, copy number 6: RNU6-433P.
- chr2:59,014,354–76,698,996, 398 genes, copy number 7–9 (broad region; genes not listed).
- chr2:76,772,909–76,773,045, 1 gene, copy number 7: RNA5SP98.
- chr2:191,229,165–200,677,064, 104 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr3:135,925,891–136,205,915, 8 genes, copy number 5: AC092989.1, NDUFS6P1, PPP2R3A, AC072039.1, AC072039.2, MSL2, TDGF1P6, AC092991.1.
- chr3:164,001,606–196,736,007, 589 genes, copy number 5–20 (within-gene range 4–20) (broad region; genes not listed).
- chr4:51,843,000–66,431,521, 192 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6–9 (broad region; genes not listed).
- chr8:32,647,202–43,514,421, 221 genes, copy number 5–22 (broad region; genes not listed).
- chr8:67,732,587–68,237,032, 5 genes, copy number 7 (within-gene range 2–7): AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1.
- chr9:60,914,407–138,203,325, 1,541 genes, copy number 5 (broad region; genes not listed).
- chr12:21,501,781–27,972,733, 121 genes, copy number 6–16 (broad region; genes not listed).
- chr12:42,929,848–52,385,652, 300 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:34,910,545–46,897,076, 217 genes, copy number 5 (broad region; genes not listed).
- chr14:98,711,613–100,306,547, 38 genes, copy number 5 (within-gene range 2–5): C14orf177, AL132796.1, AL132796.3, AL132796.2, RPL3P4, AL162151.2, AL162151.3, AL162151.1, BCL11B, AL109767.1, AL132819.1, SETD3, RNU6-91P, CCNK, CCDC85C, AL110504.1, Y_RNA, AL160313.1, HHIPL1, CYP46A1, AL160313.2, EML1, RNU1-47P, VDAC3P1, EVL, AL133368.1, AL133368.2, AL157912.1, MIR151B, MIR342, DEGS2, AL133523.1, YY1, AL157871.5, MIR6764, AL157871.6, SLC25A29, AL157871.1.
- chr15:34,140,674–101,933,350, 1,721 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr16:74,999,024–76,560,757, 47 genes, copy number 10–18 (within-gene range 4–18): ZNRF1, AC099508.1, LDHD, AC099508.2, ZFP1, AC009078.1, CTRB2, CTRB1, AC009078.2, BCAR1, AC009078.3, RNU6-758P, CFDP1, AC009054.1, AC009054.2, AC009163.2, AC009163.5, AC009163.7, TMEM170A, AC009163.4, CHST6, AC009163.1, AC009163.6, TMEM231P1, AC009163.3, CHST5, TMEM231, AC025287.1, AC025287.2, GABARAPL2, AC025287.3, ADAT1, KARS1, AC025287.5, TERF2IP, AC025287.4, DUXB, RN7SL520P, ATP5PBP7, CPHXL, AC105430.1, RNA5SP430, AC099511.1, AC010528.1, RPL18P13, AC010528.2, CNTNAP4.
- chr16:76,287,630–76,469,595, 2 genes, copy number 10: RN7SKP233, SNORD33.
- chr18:20,946,906–21,870,953, 24 genes, copy number 6 (within-gene range 1–6): ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1.
- chr18:25,818,234–40,247,367, 187 genes, copy number 7–10 (broad region; genes not listed).
- chr22:21,001,886–30,979,395, 495 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr22:37,469,063–39,532,761, 111 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,475. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
